Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A002, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A002-01A (Primary Tumor).

Sample ID #.

Diagnosis:

Section of resected colon (rectosigmoid) with a rectal carcinoma of the histological type of a moderately differentiated colorectal adenocarcinoma, extending a max of 4 cm to the aboral resection margin and measuring 3.3 cm in diameter at the widest point. Invasive spread of the tumor. Invasive spread of the tumor to the inner layers of the muscularis propria.

Oral and aboral resection border is tumor-free.

34 local lymph nodes are tumor-free with uncharacteristically reactive changes.

Stage of tumor: pT2 pN0 (0/34) G2 R0.

1CD-0-3

Adenocarcinoma, NOS 8/40/3

Site: Rectum C20.9 /w 3/31/11

Source: NCI Genomic Data Commons file ab302309-3283-47ea-9d6a-cf21b47f1120 (TCGA-AG-A002.38822F85-41C1-4CB0-8E8B-8A38643D6507.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).